Somatic mutation profile of tumor specimen TCGA-DS-A7WI-01A (aliquot TCGA-DS-A7WI-01A-12D-A351-09) from TCGA case TCGA-DS-A7WI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G2; Age at diagnosis: 43.7 years (15,970 days).
Specimen TCGA-DS-A7WI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d49e8dfc-2172-466a-9a22-316fb4c0db68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A7WI-10A (Blood Derived Normal), aliquot TCGA-DS-A7WI-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1e204a9-796a-40d0-b1b1-cfff3b2c4d7f

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF5 | c.542G>C p.R181T | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.025); catalogued as rs746273665; called by muse, mutect2
- BCL6B | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1013591816, COSV99546690; called by muse, mutect2, varscan2
- INSR | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as rs764221583, CM070168, COSV57157524; called by muse, mutect2, varscan2
- MYH3 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56861722; called by muse, mutect2, varscan2
- OR13C8 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs767536072; called by muse, mutect2, varscan2
- PPP2R5B | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as rs772174283, COSV51214045; called by muse, varscan2
- WNT7B | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs775134985, COSV100254907; called by muse, mutect2, varscan2
- ZNF442 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs372883273; called by muse, mutect2, varscan2
- AKAP13 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CASP8 | c.1019T>G p.F340C (on ENST00000432109 / NM_033355.3; = p.F357C on NM_001228.4) | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG3 | c.736A>C p.N246H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HS3ST3A1 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- MARS2 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.55); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MMP16 | c.1705A>C p.I569L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- NLGN4X | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.1618A>T p.N540Y | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- RHOV | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- SEMA6D | c.1647-4A>C | Splice Region (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- SERPINI1 | c.374T>G p.L125W | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SHROOM2 | c.2577G>T p.E859D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SHROOM2 | c.2578A>G p.K860E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRIP12 | c.3632dup p.N1212* | Frame Shift Ins (INS) | VAF 32/51 reads (63%) | called by mutect2, pindel, varscan2
- ZNF529 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- BPIFC | c.24C>A p.V8= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV55911933; called by muse, mutect2, varscan2
- GMDS | c.309A>T p.T103= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- MYO5B | c.2610C>T p.H870= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs566021600, COSV99543832; called by muse, mutect2, varscan2
- SPACA1 | c.360T>C p.D120= | Silent (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- STAG2 | c.1596G>A p.A532= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs778891520; called by muse, mutect2, varscan2
- TSHZ3 | c.420G>A p.Q140= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- ZNF493 | c.699C>T p.S233= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs563481308, COSV62749102; called by muse, mutect2, varscan2
